Somatic mutation profile of tumor specimen MP2PRT-PARPTV-TMP1-A (aliquot MP2PRT-PARPTV-TMP1-A-1-0-D-A82A-36) from MP2PRT case MP2PRT-PARPTV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.1 years (749 days).
Specimen MP2PRT-PARPTV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfaf7d3d-65d2-4353-9358-8af8c8448aee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARPTV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARPTV-NB1-A-1-0-D-A82A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4df07ffd-92f7-4ebd-b1c8-f50d3bb4c7cd

The open-access MAF lists 24 somatic variants for this specimen: 16 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 6, 3'Flank 2, In Frame Ins 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.6320C>T p.A2107V | Missense Mutation (SNP) | VAF 272/668 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV54962245; called by muse, mutect2, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 62/329 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALPK3 | c.4475C>T p.A1492V | Missense Mutation (SNP) | VAF 85/369 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.058); catalogued as rs538810746, COSV99360990, COSV99361044; called by muse, mutect2, varscan2
- PAX5 | c.365G>C p.R122P | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); catalogued as COSV63906191; called by muse, mutect2
- PBX4 | c.277G>A p.V93M | Missense Mutation (SNP) | VAF 211/508 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.286); catalogued as rs570261973, COSV104379076; called by muse, mutect2, varscan2
- RHOD | c.328C>T p.R110W | Missense Mutation (SNP) | VAF 132/319 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs781618855, COSV58211967; called by muse, mutect2, varscan2
- SNRNP40 | c.973G>A p.G325S | Missense Mutation (SNP) | VAF 156/408 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1407984982, COSV55276250; called by muse, mutect2, varscan2
- EP300 | c.3996_3997insCCC p.T1332_V1333insP | In Frame Ins (INS) | VAF 76/429 reads (18%) | called by mutect2, pindel, varscan2
- IGHV1-58 | c.348_349insAGAGGGGG p.A117Rfs*? | Frame Shift Ins (INS) | VAF 8/68 reads (12%) | called by mutect2, pindel
- IL12B | c.146C>A p.T49N | Missense Mutation (SNP) | VAF 197/467 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- IRF1 | c.256_257insCCCCGA p.M85_N86insTP | In Frame Ins (INS) | VAF 144/398 reads (36%) | called by mutect2, pindel, varscan2
- KIT | c.2680C>A p.H894N | Missense Mutation (SNP) | VAF 161/409 reads (39%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PRPF8 | c.209_210insGGTGGGAG p.I70Mfs*10 | Frame Shift Ins (INS) | VAF 107/611 reads (18%) | called by mutect2, pindel, varscan2
- SETD1B | c.1930G>A p.D644N | Missense Mutation (SNP) | VAF 112/541 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TBX4 | c.593T>A p.I198N | Missense Mutation (SNP) | VAF 102/592 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB38 | c.2160C>A p.S720R | Missense Mutation (SNP) | VAF 52/586 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- ANKRD9 | c.78G>A p.A26= | Silent (SNP) | VAF 222/434 reads (51%) | catalogued as rs1257329852; called by muse, mutect2, varscan2
- DPP6 | c.1995C>T p.S665= (on ENST00000377770 / NM_001364500.2; = p.S603= on NM_001936.5) | Silent (SNP) | VAF 357/788 reads (45%) | catalogued as rs558465693, COSV59614400, COSV59626248; called by muse, mutect2, varscan2
- GPR39 | c.1173G>A p.P391= | Silent (SNP) | VAF 47/786 reads (6%) | catalogued as rs761843800; called by muse, mutect2
- KRT6B | c.576C>T p.D192= | Silent (SNP) | VAF 144/1024 reads (14%) | catalogued as rs757944028; called by muse, mutect2, varscan2
- MCF2L | c.789C>T p.D263= (on ENST00000375608; = p.D231= on NM_024979.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 234/624 reads (38%) | catalogued as rs748020871; called by muse, mutect2, varscan2
- ZDHHC20 | c.672C>T p.V224= | Silent (SNP) | VAF 85/421 reads (20%) | called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 ins CC | 3'Flank (INS) | VAF 43/188 reads (23%) | called by mutect2, pindel*, varscan2*
- TRDV2 | chr14:22423042 ins TCCA | 3'Flank (INS) | VAF 40/63 reads (63%) | called by mutect2, pindel, varscan2
